Somatic mutation profile of tumor specimen TCGA-MK-A4N7-01A (aliquot TCGA-MK-A4N7-01A-11D-A257-08) from TCGA case TCGA-MK-A4N7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 20.7 years (7,570 days).
Specimen TCGA-MK-A4N7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bed8517-aed2-4e7f-8f39-64898cf199c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MK-A4N7-10A (Blood Derived Normal), aliquot TCGA-MK-A4N7-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ca2186a-0aee-46d3-b2f6-821d53455ef7

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOT7 | c.995A>T p.Y332F (on ENST00000377855 / NM_181864.3; = p.Y322F on NM_007274.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV64112648; called by muse, mutect2, varscan2
- AKAP12 | c.1996C>A p.P666T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV53572552; called by muse, mutect2, varscan2
- FBXL5 | c.965A>G p.H322R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.073); catalogued as COSV58010295; called by muse, mutect2, varscan2
- FGFR2 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as COSV60643477; called by muse, mutect2, varscan2
- GABRQ | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as rs1381582374, COSV64781388; called by muse, mutect2
- MAP2 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV52286155; called by muse, mutect2, varscan2
- MCM8 | c.1817C>G p.S606C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54512174; called by muse, mutect2, varscan2
- MYT1L | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746083137, COSV67714781; called by muse, mutect2, varscan2
- RELN | c.5446C>A p.L1816I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV58993531; called by muse, mutect2, varscan2
- SIKE1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50258682; called by muse, mutect2, varscan2
- SOWAHD | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as COSV59649518; called by muse, mutect2, varscan2
- SVEP1 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV57032874; called by muse, mutect2, varscan2
- ZFR2 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs754698201, COSV53597329; called by muse, mutect2, varscan2
- ZNRF3 | c.1976C>G p.S659C (on ENST00000544604 / NM_001206998.2; = p.S559C on NM_032173.3) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs563982294, COSV60432398; called by muse, mutect2, varscan2
- CDC42BPB | c.3990C>G p.L1330= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100775299, COSV63475788; called by mutect2, varscan2
- EGFL8 | c.357G>A p.L119= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100247150; called by muse, mutect2, varscan2
- HUWE1 | c.10221C>T p.S3407= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs781788404, COSV53339847; called by muse, mutect2, varscan2
- LOXL2 | c.1740C>T p.L580= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1417308396, COSV66690876; called by muse, mutect2
- VPS11 | c.870C>G p.V290= (on ENST00000620429; = p.V834= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV53827994; called by muse, mutect2
